Somatic mutation profile of tumor specimen 0E13AW from CCDI case PBCVWD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E13AW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f5fadf9-7e53-43f2-b1ad-b4903705cd10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E13B8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/196342d8-f451-49ab-9641-e8da6d21d625

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, Splice Region 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL6 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51651952; called by muse, mutect2, varscan2
- KIR2DL1 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 157/324 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs772368469, COSV52412920; called by muse, mutect2, varscan2
- MYO9A | c.2572G>C p.E858Q | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1322836849; called by muse, mutect2, varscan2
- PSD4 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 127/250 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1201826387; called by muse, mutect2, varscan2
- SYCP2 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 15/294 reads (5%) | catalogued as rs1255926611, COSV100698102; called by muse, mutect2
- BCAN | c.1382A>G p.D461G | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42SE1 | c.-560_-559insACC | Splice Region (INS) | VAF 31/69 reads (45%) | called by mutect2, pindel*, varscan2*
- CYLC1 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 94/106 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FRMD1 | c.812A>T p.K271M | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KBTBD3 | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 131/445 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOA | c.3156G>T p.Q1052H (on ENST00000286149; = p.Q1038H on NM_144672.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by mutect2, varscan2
- SPATA12 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SPTA1 | c.6185T>C p.M2062T | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31D1 | c.1965C>A p.P655= | Silent (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- CCDC39 | c.1528-70T>C | Intron (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- FGD2 | c.1326+57C>A | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
